Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KO, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KO-01A (Primary Tumor).

[page 1 of 3]
Department of Pathology

Page 1 of 4

REPORT Tel:

Unit No

Clinical Consultant & Location

Sex

This Copy For:

SPECIMEN

Right eye globe

CLINICAL DETAILS

Tumour size: 16.24 x 10.81 x 14.79mm
History of blurred vision. Visual field defect. Pain since 6 months.

MACROSCOPIC DESCRIPTION

A fresh, intact right globe.

Dimensions: Axial 25mm, Horizontal 24.5mm, Vertical 24mm

Cornea: Horizontal 11.5mm, Vertical 11mm

Optic nerve
Length 12.5mm, Diameter 4mm

Pupil: regular

On trans-illumination, a shadow is seen in the supero medial measuring 19mm in maximum diameter.

Plane of section: vertical oblique

Intraocular description:

On opening, a nodular, pale mass is seen, slightly anterior to the equator.

Tumour size
LBD 9mm, Height 8.5mm

MICROSCOPY

Sections show a virtually non-pigmented choroidal melanoma extending from the ora serrata / pars plana up to the equator. Tumour consists predominantly of spindle cells. The number of mitosis is approximately 4/40 high power fields. Closed loops are focally present in the planes of sections. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is no tumour extension

*ICD-O-3
Melanoma, spindle cell, type B 8774/3
Site B Choroid C64.3
W11/17/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

through the sclera, optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is shallow. The iris shows no significant abnormality. Ciliary processes away from tumour show slight hyalinisation. Retina overlying the tumour is slightly atrophic and Bruch's membrane appears intact.

DIAGNOSIS

Right eye, enucleation: Choroidal melanoma of predominantly spindle cell type.

COMMENT

Immunohistochemistry will be carried out for completion. In addition, molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT -

Immunohistochemistry confirms that tumour cells express Melan-A and HSP 27 (score 2).

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	2= Closed loops
NECROSIS	No

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

PIGMENTATION No
LYMPHOCYTIC INFILTRATION No
MITOTIC FREQUENCY 4/40 HPF
DIFFUSE MELANOMA No

SPREAD 1= No

CLEARANCE 2= Adequate

HSP-27 POSITIVITY 2= 21-70%

LARGE DIAMETER 9 mm
THICKNESS 8.5 mm

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 37 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

essentially normal chromosome 1p,
3 borderline losses of chromosome 3 in the presence of 3
borderline gains,
gains in chromosome 6p
and normal chromosome 8.

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file 6c5fbd37-d9c4-4045-bbc6-0d59c23b808e (TCGA-VD-A8KO.21AF9D90-AD49-4757-B96A-F536F40408E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).